Somatic mutation profile of tumor specimen TCGA-4Z-AA86-01A (aliquot TCGA-4Z-AA86-01A-11D-A391-08) from TCGA case TCGA-4Z-AA86, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.0 years (24,465 days).
Specimen TCGA-4Z-AA86-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08f677c0-6f71-49a6-8550-451c7923751b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA86-10A (Blood Derived Normal), aliquot TCGA-4Z-AA86-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb1b69d-be08-48fc-9206-553a262b0fcf

The open-access MAF lists 245 somatic variants for this specimen: 179 protein-altering or splice-affecting, 56 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 56, Nonsense Mutation 20, RNA 4, Intron 3, Frame Shift Del 2, Splice Site 2, 5'UTR 2, Splice Region 1, 3'UTR 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as rs267606624, CM105627, COSV99404727; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV55958092; called by muse, mutect2, varscan2
- ADGRL4 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV66060941; called by muse, mutect2
- AEBP2 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99857341; called by muse, mutect2
- AHNAK | c.3473C>G p.S1158* | Nonsense Mutation (SNP) | VAF 66/220 reads (30%) | catalogued as COSV99945052; called by muse, mutect2, varscan2
- AKT3 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55630816; called by muse, mutect2, varscan2
- ALG2 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV53060735; called by muse, mutect2, varscan2
- AMZ2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200439485; called by muse, mutect2, varscan2
- ANKRD45 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV60962418; called by muse, mutect2, varscan2
- ARHGAP30 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs755079157, COSV63518974; called by muse, mutect2
- ASPHD2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53220234, COSV53220547; called by mutect2, varscan2
- ATAD5 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV58978323; called by muse, mutect2, varscan2
- ATP13A1 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.159); catalogued as rs1230065025, COSV52290797; called by muse, mutect2, varscan2
- ATP2A1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63920944, COSV63922283; called by muse, mutect2, varscan2
- BICRAL | c.2453-1G>A p.X818_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV58408209; called by muse, mutect2, varscan2
- BICRAL | c.3015G>C p.K1005N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV58408218; called by muse, mutect2, varscan2
- BIRC6 | c.13282G>C p.E4428Q | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV70204891; called by muse, mutect2, varscan2
- BPIFB3 | c.58C>G p.P20A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64958097; called by muse, mutect2, varscan2
- BPTF | c.3820C>T p.L1274F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); catalogued as COSV58845774; called by muse, mutect2, varscan2
- BUB1B | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs552380700, COSV55016219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf46 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100215402, COSV55153182; called by muse, mutect2
- C2orf16 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV68843002; called by muse, mutect2, varscan2
- C2orf16 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV68646966; called by muse, mutect2, varscan2
- CASQ2 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV54773636; called by muse, mutect2
- CCDC30 | c.748C>G p.Q250E (on ENST00000340612; = p.Q207E on NM_001080850.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV59609074; called by muse, mutect2, varscan2
- CCNH | c.911C>G p.S304* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | catalogued as rs1228332596, COSV99169569; called by muse, mutect2
- CCT8L2 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV63463675, COSV99068270; called by muse, mutect2, varscan2
- CDH22 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1246016132, COSV64839486; called by muse, mutect2, varscan2
- CELF3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as rs1057188645, COSV51885522; called by muse, mutect2
- CEP350 | c.8458G>A p.E2820K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as rs755417181, COSV62606442; called by muse, mutect2, varscan2
- CERK | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV53450139, COSV53453110; called by muse, mutect2, varscan2
- CHD2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.492); catalogued as COSV100560401, COSV100560686; called by muse, mutect2
- CLEC1A | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV59533892; called by muse, mutect2, varscan2
- CR1 | c.4577C>G p.S1526C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV65462549; called by muse, mutect2, varscan2
- CREBBP | c.3233C>A p.S1078* | Nonsense Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as COSV99268019; called by muse, mutect2, varscan2
- CTIF | c.1107G>C p.Q369H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV56485925; called by muse, mutect2
- CYP2C19 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV64909151; called by muse, mutect2, varscan2
- DCAF7 | c.993C>G p.I331M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV60408602; called by muse, mutect2, varscan2
- DENND4A | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV101475230; called by muse, mutect2, varscan2
- DGKB | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs371813279, COSV51785125; called by muse, mutect2
- DIP2A | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59485971; called by muse, mutect2, varscan2
- DLG5 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64946383; called by muse, mutect2, varscan2
- DPH7 | c.942G>C p.K314N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as COSV53023848; called by mutect2, varscan2
- DRC7 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100395313; called by muse, mutect2
- DSP | c.2022G>C p.K674N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV65795424; called by muse, mutect2, varscan2
- EGLN1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as CD080824, COSV64147751; called by muse, mutect2, varscan2
- EIF4B | c.1756-1G>C p.X586_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV50407021; called by muse, mutect2, varscan2
- ELMOD2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60271429; called by muse, mutect2, varscan2
- EPPK1 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs782210706; called by muse, mutect2
- ESPL1 | c.294A>C p.E98D | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57762881; called by muse, mutect2, varscan2
- FANCC | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs370346767, CM128673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL7 | c.1123T>C p.C375R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61652480; called by muse, mutect2, varscan2
- FCER1G | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1191289789, COSV57154366; called by muse, mutect2
- FLG | c.2450G>C p.R817T | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV64247842; called by muse, varscan2
- FLG | c.2023G>C p.D675H | Missense Mutation (SNP) | VAF 104/469 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs140188504, COSV64247847; called by muse, mutect2, varscan2
- FLG2 | c.4031G>C p.R1344T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV66167335, COSV66172461; called by muse, mutect2, varscan2
- FLNA | c.6199G>T p.E2067* (on ENST00000369850 / NM_001110556.2; = p.E2059* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100774177; called by muse, mutect2, varscan2
- FLT3 | c.596G>C p.C199S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV54068181; called by muse, mutect2, varscan2
- FNBP1 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV63090136; called by muse, mutect2, varscan2
- FRAS1 | c.2344C>T p.H782Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV53642885; called by muse, varscan2
- FRMD4A | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV52734959; called by muse, mutect2, varscan2
- GABRB3 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as COSV54669135, COSV54681518; called by muse, mutect2, varscan2
- GBA2 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62306724; called by muse, mutect2, varscan2
- GJA9 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62532758; called by muse, mutect2, varscan2
- GRIA1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV53621944; called by muse, mutect2
- H2BC21 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2
- HSPD1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV61443427, COSV61446053; called by muse, mutect2, varscan2
- HTR3B | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV52746169, COSV52747343; called by muse, mutect2, varscan2
- INVS | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs778164167, COSV52449001, COSV52449474; called by muse, mutect2
- IQCH | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs776012794, COSV60051133; called by muse, mutect2, varscan2
- ITGB8 | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV56013746; called by muse, mutect2, varscan2
- KCNH3 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs748535756, COSV57792603; called by muse, mutect2, varscan2
- KIF3C | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV53099715, COSV53101552; called by muse, mutect2
- LAX1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs753768323, COSV65848812; called by muse, mutect2, varscan2
- LCOR | c.1780T>A p.C594S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV53718124; called by mutect2, varscan2
- LRRTM1 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99701514; called by muse, mutect2, varscan2
- MAP3K19 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100208154, COSV59641792; called by muse, mutect2
- MARCHF10 | c.2277G>C p.Q759H | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60890163; called by muse, mutect2
- MARCHF10 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60888453; called by muse, mutect2
- MDGA2 | c.1930G>A p.E644K (on ENST00000399232 / NM_001113498.2; = p.E346K on NM_182830.4) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.266); catalogued as COSV62113224; called by muse, mutect2, varscan2
- MED23 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV63436826; called by muse, mutect2, varscan2
- MFHAS1 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV52286542; called by muse, mutect2, varscan2
- MINK1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61793011; called by muse, mutect2, varscan2
- MPL | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV65246462, COSV65246911; called by muse, mutect2, varscan2
- MPZ | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.694); catalogued as COSV60669214; called by muse, mutect2
- MUC5B | c.3618C>A p.F1206L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1407624936, COSV101499927, COSV71592086; called by muse, mutect2
- NCAM2 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.152); catalogued as rs1388555903, COSV53100552; called by muse, mutect2, varscan2
- NCAPG2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100690135; called by muse, mutect2
- NID1 | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV51628054; called by muse, mutect2, varscan2
- NLRP9 | c.2262G>C p.L754F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60467293; called by muse, mutect2, varscan2
- NRROS | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60747578; called by muse, mutect2, varscan2
- OR10K1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56872881, COSV56873859; called by muse, mutect2, varscan2
- OR52N2 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1348199120, COSV57677773; called by muse, mutect2, varscan2
- OR8J3 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV56882025; called by muse, mutect2
- PAIP1 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV59087557; called by muse, varscan2
- PARP2 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV51641875; called by muse, mutect2, varscan2
- PC | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58993971; called by muse, mutect2, varscan2
- PC | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs760108147, COSV58993975; called by muse, mutect2, varscan2
- PCARE | c.3369C>G p.F1123L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV59057687; called by muse, mutect2, varscan2
- PEX19 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 25/517 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.538); catalogued as COSV63619768; called by muse, mutect2
- PLEKHA6 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55339628, COSV55342039; called by muse, mutect2, varscan2
- PLOD3 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99777720; called by muse, mutect2, varscan2
- PPM1B | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 8/99 reads (8%) | catalogued as COSV99175667; called by muse, mutect2
- PPP1R36 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV53903769; called by muse, varscan2
- PPP1R36 | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53903784, COSV53904132; called by muse, varscan2
- PRAMEF1 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 52/415 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60017446; called by muse, varscan2
- PRG4 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66622904; called by muse, mutect2, varscan2
- PRKG1 | c.1313G>A p.R438K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.051); catalogued as COSV64777033; called by muse, mutect2, varscan2
- PRL | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1413761259, COSV60591945; called by muse, mutect2, varscan2
- PRPF3 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100254371; called by muse, mutect2
- PRRC2B | c.6061C>A p.P2021T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV100260788; called by muse, mutect2
- PTH1R | c.1470del p.S491Afs*15 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV57315072; called by mutect2, pindel, varscan2
- RAP1GDS1 | c.49G>A p.D17N (on ENST00000408927 / NM_001100427.2; = p.D18N on NM_021159.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52791388; called by muse, mutect2, varscan2
- RAPH1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as COSV57357202; called by muse, mutect2, varscan2
- RASA3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs770658076, COSV61872782; called by muse, mutect2
- RB1 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV57296539, COSV57308308; called by muse, mutect2, varscan2
- RBBP8NL | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs1387936865, COSV53350498, COSV53350852; called by muse, mutect2
- RFPL2 | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50716632; called by muse, varscan2
- RFWD3 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100736161, COSV63099402; called by muse, mutect2
- RGS12 | c.1431T>G p.C477W | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV60909616; called by muse, mutect2, varscan2
- RHOB | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55357146; called by muse, mutect2, varscan2
- RNF128 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV60950492; called by muse, mutect2, varscan2
- RORC | c.1518C>A p.F506L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59095347; called by muse, mutect2, varscan2
- RPS8 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1336245827, COSV63234356, COSV63234575; called by muse, mutect2, varscan2
- RUNX2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM104833, COSV100766996; called by muse, mutect2, varscan2
- SETD2 | c.4999C>T p.Q1667* | Nonsense Mutation (SNP) | VAF 46/166 reads (28%) | catalogued as COSV57437153; called by muse, mutect2, varscan2
- SLC22A2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs144834632; called by muse, mutect2
- SLC25A44 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs140016645; called by muse, mutect2, varscan2
- SLC35F3 | c.601G>A p.D201N (on ENST00000366617 / NM_001300845.1; = p.D270N on NM_173508.4) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64021471; called by muse, mutect2
- SLC6A6 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV62648279, COSV62652414; called by muse, mutect2, varscan2
- SLC9A1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56056460; called by muse, mutect2, varscan2
- SLX4 | c.3601C>G p.Q1201E | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs758163209, COSV53568022; called by muse, mutect2, varscan2
- SLX4 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs138344471; ClinVar: uncertain significance; called by mutect2, varscan2
- SMU1 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV68140293; called by muse, mutect2, varscan2
- SPCS2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759670859, COSV99734261; called by muse, mutect2, varscan2
- SPTLC2 | c.1581G>C p.E527D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV53642721; called by muse, mutect2, varscan2
- SUPT20H | c.632C>T p.P211L (on ENST00000350612 / NM_001014286.3; = p.P212L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62249453; called by muse, mutect2, varscan2
- TAF11 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV51954413, COSV51956619, COSV99511305; called by muse, mutect2, varscan2
- TAF5L | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV51089242; called by muse, mutect2
- TASOR2 | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV60169394; called by muse, mutect2
- TBX22 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV64787671; called by muse, mutect2, varscan2
- TECRL | c.333C>T p.G111= | Splice Region (SNP) | VAF 12/77 reads (16%) | catalogued as rs535849187, COSV67085280; called by muse, mutect2, varscan2
- TGM5 | c.1739C>G p.S580C (on ENST00000220420 / NM_201631.4; = p.S498C on NM_004245.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV55011991; called by muse, mutect2, varscan2
- THEM5 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs765469169, COSV64312756; called by muse, mutect2, varscan2
- TLR10 | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs371911164; called by muse, varscan2
- TLR10 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs199605976, COSV58299237; called by muse, mutect2, varscan2
- TMEM131 | c.2572G>C p.D858H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318141880, COSV51785033; called by muse, mutect2, varscan2
- TMPRSS11F | c.1301C>G p.S434* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100677980; called by muse, mutect2, varscan2
- TMTC1 | c.1046T>C p.I349T (on ENST00000539277 / NM_001193451.2; = p.I241T on NM_175861.3) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV55492482; called by muse, varscan2
- TOR1AIP1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs373411869; called by muse, mutect2, varscan2
- TRMO | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64293607; called by muse, mutect2, varscan2
- TTC7A | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.792); catalogued as rs977730780, COSV99765821; called by muse, mutect2
- TXNRD1 | c.1185C>G p.I395M (on ENST00000525566 / NM_001093771.3; = p.I297M on NM_003330.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV61601264; called by muse, mutect2, varscan2
- UBXN2B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs762270373, COSV68309666; called by muse, mutect2, varscan2
- USP4 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV55540209; called by muse, mutect2, varscan2
- USP9X | c.3692G>C p.R1231T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100198270; called by muse, mutect2, varscan2
- UTP6 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV55575375; called by muse, mutect2, varscan2
- WDFY3 | c.7549G>A p.E2517K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV55712530; called by muse, mutect2, varscan2
- WDFY3 | c.4457G>C p.G1486A | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); catalogued as COSV55712539; called by muse, mutect2, varscan2
- WDR17 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.627); catalogued as rs372005755; called by muse, mutect2
- WDR17 | c.3238G>C p.E1080Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV99706391; called by muse, mutect2
- XIRP2 | c.6992G>A p.G2331E (on ENST00000628543; = p.G2506E on NM_152381.6) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54715957; called by muse, mutect2, varscan2
- XRN1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV53817420, COSV99056023; called by muse, mutect2, varscan2
- XRN1 | c.764G>C p.R255T | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53817438; called by muse, mutect2
- ZNF285 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV58410752; called by muse, mutect2, varscan2
- ZNF507 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753251656, COSV61333175; called by muse, mutect2, varscan2
- ZNF532 | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs764368512, COSV60172732; called by muse, mutect2, varscan2
- ZNF585A | c.1114C>T p.H372Y (on ENST00000292841 / NM_001288800.2; = p.H317Y on NM_152655.3) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1434086298, COSV53066690; called by muse, mutect2, varscan2
- ZNF616 | c.1097C>G p.S366* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | catalogued as COSV57513050; called by muse, mutect2
- ZNF74 | c.1416C>G p.F472L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV62623577; called by muse, mutect2, varscan2
- ZNF782 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV56654745; called by muse, mutect2, varscan2
- ZNF836 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100440461; called by muse, mutect2, varscan2
- CD244 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- CNOT3 | c.748del p.E250Rfs*85 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MICAL2 | c.2598_2600del p.K866del | In Frame Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- RAD17 | c.298C>T p.Q100* (on ENST00000380774 / NM_133339.2; = p.Q89* on NM_002873.1) | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- TRAV36DV7 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ACSM4 | c.975G>A p.R325= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV68069190; called by muse, mutect2
- ADPRS | c.513G>A p.Q171= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV52882233; called by muse, mutect2, varscan2
- AHNAK | c.15165C>G p.L5055= | Silent (SNP) | VAF 39/301 reads (13%) | catalogued as COSV57228168; called by muse, mutect2, varscan2
- AHNAK | c.13764C>T p.L4588= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV57228189; called by muse, mutect2, varscan2
- ARHGAP32 | c.2688A>G p.G896= (on ENST00000310343 / NM_001378025.1; = p.G547= on NM_014715.4) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV59854952; called by muse, mutect2, varscan2
- BIRC6 | c.3930A>G p.S1310= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV70204885; called by muse, mutect2, varscan2
- CDH22 | c.345G>C p.L115= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV64839489; called by muse, mutect2, varscan2
- CLTCL1 | c.3651C>G p.L1217= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99594277; called by muse, mutect2
- COL3A1 | c.132C>G p.V44= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV58595636; called by muse, mutect2, varscan2
- CP | c.819C>G p.L273= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV52833446; called by muse, mutect2, varscan2
- FLG | c.2880G>A p.E960= | Silent (SNP) | VAF 81/521 reads (16%) | catalogued as COSV64247837; called by muse, mutect2, varscan2
- FRAS1 | c.2379C>T p.S793= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs368659218; called by muse, varscan2
- FZD10 | c.864C>T p.I288= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV57471949; called by muse, mutect2, varscan2
- HSPA1A | c.1731C>T p.V577= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV65149454; called by muse, mutect2, varscan2
- IQSEC2 | c.2289C>G p.L763= (on ENST00000642864 / NM_001111125.3; = p.L558= on NM_015075.2) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV64727689; called by muse, mutect2, varscan2
- ITGA8 | c.429C>T p.H143= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV65235041; called by muse, mutect2, varscan2
- KDSR | c.153G>A p.E51= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs1307395376, COSV58508063; called by muse, mutect2, varscan2
- KLHL10 | c.126C>T p.V42= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV53174632; called by muse, mutect2
- KRIT1 | c.1824C>G p.L608= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100388536; called by muse, mutect2
- LCLAT1 | c.459C>G p.L153= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV58377916; called by muse, mutect2, varscan2
- LRP1 | c.1581C>T p.F527= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99673726; called by muse, mutect2
- MAP6 | c.1020C>T p.F340= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV59077602; called by muse, mutect2, varscan2
- MINK1 | c.675G>A p.E225= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV61793022; called by muse, mutect2, varscan2
- MROH2B | c.3897G>C p.G1299= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV68181301, COSV68188894; called by muse, mutect2, varscan2
- MYOF | c.3408C>G p.V1136= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV63710006; called by muse, mutect2, varscan2
- OR2T10 | c.504C>T p.F168= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV57898235; called by muse, mutect2, varscan2
- OR2T10 | c.276C>T p.I92= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs752484861, COSV57896350, COSV57898253; called by muse, mutect2, varscan2
- OR51B4 | c.810C>A p.P270= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV66517705; called by muse, mutect2, varscan2
- OR5H15 | c.874C>T p.L292= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV62948943; called by muse, mutect2, varscan2
- PCDHA10 | c.1162C>T p.L388= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV56540655; called by muse, mutect2, varscan2
- PLEKHA6 | c.1330C>T p.L444= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1370250041, COSV55339623; called by muse, mutect2, varscan2
- PMS2 | c.360C>T p.V120= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs767313783, COSV56223763; ClinVar: likely benign; called by muse, mutect2
- PRKAR1B | c.462C>T p.F154= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV64317881; called by muse, mutect2
- PTGDR | c.930A>G p.R310= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60094956; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1218G>C p.L406= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV50247982; called by muse, mutect2, varscan2
- RNF213 | c.714C>T p.A238= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1447153262, COSV60629654; called by muse, mutect2, varscan2
- RYR3 | c.9747C>A p.L3249= (on ENST00000389232; = p.L3250= on NM_001036.6) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV66806652; called by muse, mutect2, varscan2
- SIGLEC10 | c.1041G>A p.L347= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV59486124; called by muse, mutect2
- SLC5A7 | c.57G>A p.L19= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV99886040; called by muse, mutect2
- SLIT1 | c.3795G>T p.G1265= | Silent (SNP) | VAF 29/227 reads (13%) | catalogued as COSV56597866; called by muse, mutect2, varscan2
- SLX4 | c.3459C>G p.L1153= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1252859091, COSV53568029; called by muse, mutect2, varscan2
- SPAST | c.1140C>G p.L380= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100188823, COSV59516472; called by muse, mutect2, varscan2
- SPNS3 | c.1395G>C p.L465= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100336788; called by muse, varscan2
- SPTBN4 | c.4059G>A p.L1353= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100149617; called by muse, mutect2, varscan2
- SSBP4 | c.888C>T p.I296= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs751400638, COSV54210129; called by muse, varscan2
- THUMPD3 | c.1523G>A p.*508= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100560445, COSV61505784; called by muse, mutect2, varscan2
- TMED6 | c.708G>A p.K236= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54742026, COSV54743400; called by muse, mutect2, varscan2
- TNPO1 | c.337C>T p.L113= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV61523732; called by muse, mutect2, varscan2
- TP53 | c.960G>A p.K320= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV52868386, COSV52964855, COSV53245158; called by muse, mutect2, varscan2
- TUT4 | c.4407C>G p.V1469= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV57119191; called by muse, mutect2, varscan2
- UBE2M | c.123G>A p.L41= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs999940059, COSV53043101; called by muse, mutect2, varscan2
- USP32 | c.4074G>C p.L1358= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV56276525; called by muse, mutect2
- VAMP2 | c.225C>A p.S75= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV57183778; called by muse, mutect2, varscan2
- VEPH1 | c.939G>A p.V313= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs1221738777, COSV62882141; called by muse, mutect2, varscan2
- ZMYM6 | c.633G>T p.V211= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs752989280, COSV58185326; called by muse, mutect2, varscan2
- ZNF175 | c.1536C>T p.F512= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV51798220; called by muse, mutect2, varscan2
- ABCA3 | c.-1G>A | 5'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as rs771636942, COSV100067800; called by muse, varscan2
- AGAP7P | n.1255C>A | RNA (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- CCT6A | c.1213+154C>A | Intron (SNP) | VAF 122/203 reads (60%) | catalogued as COSV99303153, COSV99303826; called by muse, mutect2, varscan2
- DCK | c.*1T>A | 3'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as COSV54378464, COSV54379744; called by muse, mutect2, varscan2
- FAM27E5 | n.403G>A | RNA (SNP) | VAF 6/46 reads (13%) | catalogued as rs779592317; called by muse, mutect2, varscan2
- GATAD2A | c.-90-1008A>G | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as rs111726405, COSV99389409; called by muse, mutect2, varscan2
- LINC01600 | n.754G>A | RNA (SNP) | VAF 4/34 reads (12%) | catalogued as rs376907981; called by mutect2, varscan2
- LINC02694 | n.90G>A | RNA (SNP) | VAF 10/85 reads (12%) | catalogued as COSV59559025; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 10/31 reads (32%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- ZNF160 | c.271+641G>T | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100762185, COSV62000801; called by muse, mutect2
